Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A0ZZ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A0ZZ-01A (Primary Tumor).

[page 1 of 4]
DIAGNOSIS:

A. Uterus, bilateral ovaries, and fallopian tubes; hysterectomy and bilateral salpingo-oophorectomy: Endometrial adenocarcinoma, mixed ~~endometrioid and serous~~ types, FIGO grade 3 (of 3) is identified within a polypoid mass in the posterior wall (1.2 x 0.6 x 0.6 cm). The tumor invades 0.2 cm into the myometrium (total myometrial thickness, 1.8 cm). Multiple (2) sessile lesions on the anterior (1.9 cm in greatest dimension) and lateral (0.5 cm in greatest dimension) walls also show a mixed endometrioid and serous adenocarcinoma (FIGO grade 3 of 3), superficially invading the myometrium to a depth of 0.1 cm. A benign endometrial polyp is present. The tumors do not involve the endocervix. The margins are negative for tumor. The bilateral ovaries and fallopian tubes are unremarkable.

B. Lymph nodes, right pelvic, lymphadenectomy: Multiple (14) right pelvic lymph nodes are negative for tumor.

C. Lymph nodes, left pelvic, lymphadenectomy: Multiple (12) left pelvic lymph nodes are negative for tumor.

D. Lymph nodes, right para-aortic, biopsy: Multiple (5) right para-aortic lymph nodes are negative for tumor.

E. Gonadal vessels, right, excision: Negative for tumor.

F. Omentum, omentectomy: Benign adipose tissue.

G. Lymph node, left para-aortic lymph nodes, biopsy: Multiple (6) left para-aortic lymph nodes are negative for tumor.

[page 2 of 4]
H. Gonadal vessels, left, excision: Negative for tumor.

This final pathology report is based on the gross/macroscopic examination and the frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

GROSS DESCRIPTION:

A. Received fresh labeled "uterus and bilateral tubes/ovaries" is an 80.0 gram uterus with attached bilateral tubes and ovaries and cervix. The uterine serosa is smooth. There is a 4.2 x 3.2 x 3.0 cm polypoid mass in the fundus of the endometrial cavity which does not grossly appear to invade into the myometrium. There are no leiomyomas. There is a 1.0 x 0.6 x 0.5 cm right ovary with a smooth outer surface and a solid cut surface with a 5.0 x 0.3 cm right fallopian tube. There is a (1.0x 0.6 x 0.5 cm) left ovary with a smooth outer surface and a solid cut surface with a 4.5 x 0.4 cm left fallopian tube. Representative sections submitted. Grossed by

B. Received fresh labeled "right pelvic lymph nodes" is a 9.0 x 6.0 x 1.3 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

[page 3 of 4]
C. Received fresh labeled "left pelvic lymph nodes" is a 9.0 x 4.0 x 1.0 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

D. Received fresh labeled "right para-aortic lymph nodes" is a 3.0 x 2.0 x 1.5 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

E. Received fresh labeled "right gonadal vessel" is a 6.2 cm in length by 0.4 cm in diameter portion of unremarkable blood vessel. A representative section is submitted.

F. Received fresh labeled "omentum" is a 27.0 x 14.0 x 1.4 cm portion of omentum. No masses are identified grossly. A lymph node is identified. Representative sections are submitted. Grossed by

G. Received fresh labeled "left para-aortic lymph nodes" is a 4.1 x 4.0 x 1.2 cm aggregate of adipose and lymphatic tissue. All lymphatic tissue submitted.

H. Received fresh labeled "left gonadal vessels" is a 5.0 cm in length by 1.3 cm in diameter portion of unremarkable blood vessel. A representative section is submitted.

BLOCK SUMMARY:

Part A: Uterus, tubes, ovaries

- 1 Base of fundus mass
- 2 Fundus mass

[page 4 of 4]
- 3 Ant uterine mass
- 4 Rt fundus mass
- 5 Post uterine polyp
- 6 Endometrium
- 7 LUS
- 8 Cervix 6:00
- 9 Right ovary and tube
- 10 Left overy and tube

Part B: Right Pelvic Lymph Nodes

- 1 Rt pelvic LNs-5 (B1)
- 2 Rt pelvic LN (1 of 2) (B2)
- 3 Rt pelvic LN (2 of 2) (B2)
- 4 Rt pelvic LNs-2 (B3)
- 5 Rt pelvic LN-1 (B4)
- 6 Rt pelvic LNs-4 (B5)
- 7 Rt pelvic LNs-2 (B6)

Part C: Left Pelvic Lymph Nodes

- 1 Lt pelvic LNs-5 (C1)
- 2 Lt pelvic LNs-3 (C2)
- 3 Lt pelvic LNs-4 (C3)
- 4 Lt pelvic LNs-2 (C4)

Part D: Right Para-aortic Lymph Nodes

- 1 Rt para-aortic LN (D1)
- 2 Rt para-aortic LN (D2)

Part E: Right Gonadal vessels

- 1 Right gonadal vessels

Part F: Omentum

- 1 Omentum lymphnode
- 2 Omentum

Part G: Left Para-aortic Lymph Nodes

- 1 Lt para-aortic LN3 (G1)
- 2 Lt para-aortic LN2 (G2)
- 3 Lt para-aortic LN1 (G3)

Part H: Left Gonadal vessels

- 1 Lt gonadal vessels

Source: NCI Genomic Data Commons file 3b26584f-5b31-40e1-a248-169b86db4691 (TCGA-D1-A0ZZ.4339EAC6-F56E-49E6-8EF9-2256165CADB5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).